TARGET case TARGET-15-SJMPAL044953 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1269cbbe-dd45-4647-9153-ee2c4a7d666e

Demographics
Sex at birth: male; Age at index: 14 years.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 14.4 years (5,272 days); Year of diagnosis: 2014.

Follow-up (1 entry)
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 174 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL044953-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Protocol: BFM
- WBC at Diagnosis: 174.1
- Karyotype: 46,XY[20]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
